Gene-level copy-number profile of tumor specimen TCGA-AQ-A04H-01B from TCGA case TCGA-AQ-A04H, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 61.7 years (22,539 days).
Specimen TCGA-AQ-A04H-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.965e2ec0-0a64-4ad1-a201-97cdf65dcb39.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AQ-A04H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ebeac9dd-4c47-425f-943b-0dcc03d5cc1f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 242; copy number 2: 13,847; copy number 3: 32,573; copy number 4: 9,659; copy number 5: 1,396; copy number 6: 297; copy number 7: 1,294; copy number 8: 92; copy number 9: 107; copy number 10: 155; copy number 11: 17; copy number 15: 17; copy number 16: 77; copy number 21: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AQ-A04H-01B-11D-A10L-01): tumor purity 0.72, ploidy 3.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:124,376,877–124,461,485, 8 genes: OR8C1P, OR8B2, OR8B3, OR8X1P, AP001804.1, OR8B4, OR8B8, OR8A2P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,797 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:153,067,278–153,980,186, 11 genes, copy number 7 (within-gene range 4–7): HMGN2P13, AC117394.1, AC117394.2, RAP2B, RN7SL300P, AC078788.1, AC078788.2, LINC02006, LINC02877, RNU6-901P, Y_RNA.
- chr3:166,811,009–172,604,006, 101 genes, copy number 7 (broad region; genes not listed).
- chr3:174,438,573–175,810,548, 1 gene, copy number 11 (within-gene range 6–21): NAALADL2.
- chr3:175,234,861–186,110,318, 216 genes, copy number 8–21 (broad region; genes not listed).
- chr11:67,252,336–67,784,229, 46 genes, copy number 8: AP001885.3, GRK2, ANKRD13D, SSH3, AP001885.2, RAD9A, POLD4, AP003419.1, AP003419.2, RN7SKP239, CLCF1, AP003419.3, RNU6-1238P, PPP1CA, TBC1D10C, CARNS1, RPS6KB2, RPS6KB2-AS1, PTPRCAP, CORO1B, GPR152, CABP4, TMEM134, AIP, MIR6752, PITPNM1, CDK2AP2, CABP2, AP001184.1, GSTP1, C11orf72, AP003385.3, NDUFV1, DOC2GP, NUDT8, TBX10, ACY3, AP003385.1, ALDH3B2, RPL37P2, UNC93B5, OR7E145P, OR7E11P, AP003385.5, AP003385.2, AP003385.4.
- chr11:68,612,899–70,385,312, 53 genes, copy number 10 (within-gene range 3–10): AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2.
- chr17:39,252,663–40,836,270, 74 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr17:55,882,301–57,745,299, 34 genes, copy number 8 (within-gene range 5–8): ANKFN1, AC006600.1, AC006600.2, RPL39P33, NOG, C17orf67, AC106858.1, DGKE, TRIM25, RNU6-1158P, AC015912.2, AC015912.1, MIR3614, AC015912.3, COIL, AC004584.1, AC004584.2, SCPEP1, AC004584.3, RNF126P1, AC007114.1, AKAP1, AC007114.2, AC003950.1, AC091181.2, MSI2, AC091181.1, AC015883.1, AC007431.2, AC007431.3, AC007431.1, RN7SL449P, RNU7-134P, CCDC182.
- chr17:59,331,655–71,202,203, 320 genes, copy number 7–15 (within-gene range 3–15) (broad region; genes not listed).
- chr17:71,596,338–72,640,472, 13 genes, copy number 7 (within-gene range 3–7): AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1.
- chr17:79,598,032–80,398,786, 30 genes, copy number 10 (within-gene range 4–10): AC233701.1, MIR4739, LINC02078, ENPP7, CBX2, CBX8, AC100791.2, LINC01977, CBX4, AC100791.1, LINC01979, LINC01978, TBC1D16, AC100791.3, AC116025.2, AC116025.1, CCDC40, MIR1268B, GAA, EIF4A3, AC087741.3, AC087741.2, CARD14, AC087741.1, SGSH, SLC26A11, RNF213, AC124319.1, AC124319.2, AC124319.3.
- chr20:30,278,906–64,313,132, 898 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 176. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
